CCDI case PBCCVP — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Thyroid gland.
https://portal.gdc.cancer.gov/cases/544f9f63-f6b8-426d-ac37-c118b7fbb737

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Papillary carcinoma, NOS: ICD-O-3 morphology code: 8050/3; Tissue or organ of origin: Thyroid gland; Age at diagnosis: 11.5 years (4,197 days).

Biospecimens (3 samples)
- Sample 0DP6HH: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DP6HV: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DP6OU: Tissue type: Tumor; Specimen type: Solid Tissue.
